Somatic mutation profile of tumor specimen TCGA-06-2562-01A (aliquot TCGA-06-2562-01A-01W-0837-08) from TCGA case TCGA-06-2562, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 81.5 years (29,753 days).
Specimen TCGA-06-2562-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50445038-cfa2-48a1-8358-d30982bb8ac6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-2562-10A (Blood Derived Normal), aliquot TCGA-06-2562-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad7776f0-f4c1-4275-abc8-02fb19ff6df6

The open-access MAF lists 98 somatic variants for this specimen: 73 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 23, Frame Shift Ins 9, Frame Shift Del 4, Nonsense Mutation 3, Intron 1, Splice Site 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1400del p.T467Nfs*6 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | catalogued as rs1135402808, CM087524, COSV62197770; ClinVar: pathogenic; called by mutect2, pindel
- ABCC8 | c.3760A>G p.I1254V | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV56846843; called by muse, mutect2, varscan2
- ADAM23 | c.2340dup p.K781Qfs*3 | Frame Shift Ins (INS) | VAF 12/84 reads (14%) | catalogued as rs767549806; called by mutect2, varscan2
- ADAMTS2 | c.2821C>T p.R941C | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs937744996, COSV52365650, COSV52367097; called by muse, mutect2, varscan2
- ADD2 | c.1657G>A p.V553M | Missense Mutation (SNP) | VAF 210/465 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.066); catalogued as COSV52455509; called by muse, mutect2, varscan2
- ATG5 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 123/371 reads (33%) | catalogued as COSV58346260; called by muse, mutect2, varscan2
- ATP8A1 | c.2091C>G p.H697Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs202148347, COSV52529474; called by muse, mutect2, varscan2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 40/278 reads (14%) | catalogued as rs745882580; called by mutect2, varscan2
- CALN1 | c.565G>A p.V189I (on ENST00000329008 / NM_001017440.3; = p.V231I on NM_031468.4) | Missense Mutation (SNP) | VAF 28/265 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs144352678; called by muse, mutect2, varscan2
- CAPS2 | c.1532T>C p.I511T | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV60824159; called by muse, mutect2, varscan2
- CCSER1 | c.1544A>G p.D515G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100394472, COSV61448997; called by muse, mutect2, varscan2
- CD19 | c.1153G>A p.V385I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs1378572982, COSV61188949; called by muse, mutect2
- CHAT | c.1441dup p.R481Pfs*30 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | catalogued as rs773268576; called by pindel, varscan2
- CTNND2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.212); catalogued as COSV58868041; called by muse, mutect2, varscan2
- DNAH3 | c.3310G>A p.A1104T | Missense Mutation (SNP) | VAF 130/335 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV54505767; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | catalogued as rs749150409; called by mutect2, varscan2
- HCLS1 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 152/476 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747473070, COSV57522166; called by muse, mutect2, varscan2
- ISG20L2 | c.865dup p.L289Pfs*6 | Frame Shift Ins (INS) | VAF 42/301 reads (14%) | catalogued as rs761558950; called by mutect2, varscan2
- ITGB4 | c.310dup p.Q104Pfs*11 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | catalogued as rs1437647695; called by pindel, varscan2
- KCNK10 | c.985A>G p.T329A | Missense Mutation (SNP) | VAF 119/332 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56639817; called by muse, mutect2, varscan2
- KRT13 | c.833G>A p.R278K | Missense Mutation (SNP) | VAF 439/1261 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs774263110; called by muse, mutect2, varscan2
- LRIF1 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 85/286 reads (30%) | catalogued as rs375319628; called by muse, varscan2
- LZTR1 | c.313T>C p.W105R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53145505; called by muse, mutect2, varscan2
- MAGEA4 | c.290G>T p.S97I | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs1263001898; called by muse, mutect2, varscan2
- MCF2 | c.2027T>C p.M676T | Missense Mutation (SNP) | VAF 82/152 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58478663; called by muse, mutect2, varscan2
- MYO10 | c.3674dup p.S1226Lfs*25 | Frame Shift Ins (INS) | VAF 54/439 reads (12%) | catalogued as rs760302326, COSV57018963; called by mutect2, varscan2
- NECTIN4 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.572); catalogued as COSV63511994; called by muse, mutect2, varscan2
- NF1 | c.4977_4980del p.K1661Gfs*36 (on ENST00000358273 / NM_001042492.3; = p.K1640Gfs*36 on NM_000267.3) | Frame Shift Del (DEL) | VAF 58/353 reads (16%) | catalogued as rs1085307459; called by mutect2, pindel, varscan2
- PDP2 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV61240096; called by muse, mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 24/206 reads (12%) | catalogued as rs749506841; called by mutect2, varscan2
- PIK3R1 | c.1718T>C p.L573P (on ENST00000521381 / NM_181523.3; = p.L303P on NM_181504.4) | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57124674; called by muse, mutect2, varscan2
- PKD1L1 | c.6766C>G p.L2256V | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV56971660; called by muse, mutect2
- PNISR | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 109/173 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV65078777; called by muse, mutect2, varscan2
- PPEF2 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs779962909, COSV54420431, COSV54421273; called by muse, mutect2, varscan2
- PPP1R10 | c.2336G>A p.S779N | Missense Mutation (SNP) | VAF 187/806 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as COSV64738555; called by muse, mutect2, varscan2
- PRPS1L1 | c.841A>G p.M281V | Missense Mutation (SNP) | VAF 286/2442 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV72649948; called by muse, mutect2, varscan2
- PRR16 | c.479C>A p.P160Q (on ENST00000407149 / NM_001300783.2; = p.P137Q on NM_016644.2) | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV65395149, COSV65399812; called by muse, mutect2, varscan2
- RNF43 | c.1800A>C p.R600S | Missense Mutation (SNP) | VAF 97/219 reads (44%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.018); catalogued as COSV68457003; called by muse, mutect2, varscan2
- RUSC1 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 94/327 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as COSV52742868; called by muse, varscan2
- SELE | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 72/219 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs139137736; called by muse, mutect2, varscan2
- SERPINA10 | c.1310G>T p.R437M | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1472949765, COSV56229202; called by muse, mutect2, varscan2
- SLC12A5 | c.1603G>A p.A535T (on ENST00000454036 / NM_001134771.2; = p.A512T on NM_020708.5) | Missense Mutation (SNP) | VAF 57/291 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV54789147; called by muse, mutect2, varscan2
- SLC17A1 | c.1287G>T p.W429C | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV55077541; called by muse, mutect2, varscan2
- SLC46A2 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV65289604; called by muse, mutect2, varscan2
- SLC4A10 | c.2860C>A p.Q954K (on ENST00000446997 / NM_001354461.2; = p.Q924K on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV55774551; called by muse, mutect2
- SLC4A4 | c.1228G>A p.G410R (on ENST00000264485 / NM_001098484.3; = p.G366R on NM_003759.4) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.14); catalogued as COSV52615891; called by muse, mutect2, varscan2
- SMG5 | c.1658A>G p.N553S | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.344); catalogued as rs151295845; called by muse, mutect2, varscan2
- SSTR4 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.532); catalogued as COSV54797114; called by muse, mutect2, varscan2
- STC2 | c.669dup p.E224Rfs*29 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | catalogued as rs760095741; called by pindel, varscan2
- TTN | c.61267A>G p.I20423V (on ENST00000591111; = p.I12999V on NM_003319.4) | Missense Mutation (SNP) | VAF 31/228 reads (14%) | PolyPhen benign (0.015); catalogued as COSV60194123; called by muse, mutect2, varscan2
- UPK1A | c.285G>A p.T95= | Splice Region (SNP) | VAF 7/64 reads (11%) | catalogued as rs985433105, COSV55879218; called by muse, mutect2
- XCL1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 125/250 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.195); catalogued as rs141027416; called by muse, mutect2, varscan2
- ZAN | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs746268486, COSV61812094; called by muse, mutect2, varscan2
- ZNF100 | c.3+1G>A p.X1_splice | Splice Site (SNP) | VAF 107/387 reads (28%) | catalogued as COSV64167504; called by muse, mutect2, varscan2
- ACOXL | c.1229C>T p.A410V (on ENST00000389811 / NM_001371254.1; = p.A380V on NM_001142807.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCNF | c.1894C>T p.P632S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CCNF | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- CFAP70 | c.1844C>A p.A615D | Missense Mutation (SNP) | VAF 42/290 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- FER1L6 | c.2139G>C p.Q713H | Missense Mutation (SNP) | VAF 18/536 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FNDC1 | c.5292G>T p.E1764D | Missense Mutation (SNP) | VAF 29/349 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- FOSL2 | c.308T>G p.I103S | Missense Mutation (SNP) | VAF 125/243 reads (51%) | SIFT tolerated (0.46); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GLDN | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- MAP3K19 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- PLCB1 | c.475_479del p.L159Afs*26 | Frame Shift Del (DEL) | VAF 27/114 reads (24%) | called by mutect2, pindel, varscan2
- POLN | c.1462C>T p.L488F | Missense Mutation (SNP) | VAF 28/540 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RHBG | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 334/538 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC40A1 | c.1207T>C p.S403P | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.15); called by mutect2, varscan2
- SLC40A1 | c.1004_1005del p.Q335Rfs*71 | Frame Shift Del (DEL) | VAF 31/70 reads (44%) | called by mutect2, pindel, varscan2
- SPAG5 | c.1879C>T p.Q627* | Nonsense Mutation (SNP) | VAF 51/189 reads (27%) | called by muse, mutect2, varscan2
- SUGP2 | c.1399C>A p.L467I | Missense Mutation (SNP) | VAF 27/506 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- SYT13 | c.501C>A p.D167E | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- VCAM1 | c.1448G>A p.C483Y | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZZEF1 | c.571C>A p.H191N | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.396); called by muse, mutect2
- AKAP11 | c.3723G>C p.V1241= | Silent (SNP) | VAF 16/152 reads (11%) | called by mutect2, varscan2
- APAF1 | c.1950T>G p.L650= (on ENST00000551964 / NM_181861.2; = p.L639= on NM_001160.3) | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1306625009; called by mutect2, varscan2
- ATG2B | c.4431C>T p.I1477= | Silent (SNP) | VAF 54/189 reads (29%) | called by muse, mutect2, varscan2
- CA9 | c.654G>A p.R218= | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- CACNA1I | c.2053C>T p.L685= | Silent (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- CDH7 | c.738A>G p.T246= | Silent (SNP) | VAF 47/134 reads (35%) | catalogued as COSV59882061; called by muse, mutect2, varscan2
- EPHB1 | c.2616G>A p.A872= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs760099232, COSV67659427; called by muse, mutect2, varscan2
- FBLIM1 | c.327G>A p.P109= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs138682032; called by muse, mutect2, varscan2
- GAK | c.2127G>A p.V709= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs377594780; called by muse, mutect2, varscan2
- IL4I1 | c.1650A>C p.P550= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV55577208; called by muse, mutect2, varscan2
- KMO | c.660C>G p.T220= | Silent (SNP) | VAF 16/197 reads (8%) | called by muse, mutect2
- LRP5 | c.2235G>A p.A745= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as rs750492852, COSV53711714; called by muse, mutect2, varscan2
- MAG | c.1842G>A p.T614= | Silent (SNP) | VAF 80/146 reads (55%) | catalogued as rs768107293, COSV62699113; ClinVar: likely benign; called by muse, mutect2, varscan2
- OPN1SW | c.348A>T p.V116= | Silent (SNP) | VAF 46/681 reads (7%) | catalogued as COSV50822594; called by muse, mutect2
- OR5H2 | c.855C>T p.I285= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs1265919655, COSV62350037; called by muse, mutect2, varscan2
- PIP5K1B | c.1572C>T p.N524= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as COSV55242102; called by muse, mutect2, varscan2
- POLR2G | c.255G>A p.V85= | Silent (SNP) | VAF 255/342 reads (75%) | catalogued as rs1219593749; called by muse, mutect2, varscan2
- SGCD | c.780C>T p.F260= (on ENST00000435422 / NM_001128209.2; = p.F261= on NM_000337.5) | Silent (SNP) | VAF 61/301 reads (20%) | catalogued as rs768741617, COSV61903980, COSV61905794; called by muse, mutect2, varscan2
- SLIT1 | c.1329C>T p.C443= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as rs745617207, COSV56583132; called by muse, mutect2, varscan2
- SNX11 | c.441G>A p.V147= | Silent (SNP) | VAF 20/398 reads (5%) | called by muse, mutect2
- TMEM132D | c.3195C>T p.I1065= | Silent (SNP) | VAF 215/453 reads (47%) | catalogued as rs776600445, COSV67158685; called by muse, mutect2, varscan2
- TTC26 | c.1050A>G p.G350= | Silent (SNP) | VAF 45/303 reads (15%) | catalogued as COSV58269681; called by muse, mutect2, varscan2
- TUBB1 | c.1062C>T p.C354= | Silent (SNP) | VAF 29/202 reads (14%) | catalogued as rs775221566, COSV53885972; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.400+6898C>T | Intron (SNP) | VAF 569/973 reads (58%) | catalogued as rs766745626, COSV57113200; called by muse, mutect2, varscan2
- POLR3H | c.-2G>A | 5'UTR (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
